Gene-level copy-number profile of tumor specimen TCGA-FP-A9TM-01A from TCGA case TCGA-FP-A9TM, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; Tumor grade: G2; Age at diagnosis: 77.7 years (28,376 days).
Specimen TCGA-FP-A9TM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.189156ab-a50a-4cef-9a4d-c6e83f3c5e66.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FP-A9TM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/de999bc6-cf5d-4c95-a60e-cb6ed796f8bf

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 46; copy number 2: 3,682; copy number 3: 20,217; copy number 4: 15,925; copy number 5: 9,595; copy number 6: 8,015; copy number 7: 1,815; copy number 9: 103; copy number 10: 47; copy number 12: 339; copy number 13: 5; copy number 17: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FP-A9TM-01A-11D-A396-01): tumor purity 0.28, ploidy 2.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,335 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:80,761,042–82,463,675, 14 genes, copy number 9 (within-gene range 3–9): AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008.
- chr7:89,443,946–94,431,227, 79 genes, copy number 12 (broad region; genes not listed).
- chr7:94,907,202–95,296,415, 5 genes, copy number 13 (within-gene range 5–13): PPP1R9A, HINT1P2, AC002429.1, PPP1R9A-AS1, RNU4-16P.
- chr7:96,481,626–110,592,204, 348 genes, copy number 9–12 (broad region; genes not listed).
- chr7:110,724,159–110,725,825, 1 gene, copy number 9: AC073326.1.
- chr15:42,412,823–46,827,958, 149 genes, copy number 7 (broad region; genes not listed).
- chr15:53,513,741–56,918,571, 51 genes, copy number 7 (within-gene range 5–7): WDR72, RNU2-53P, RNU6-449P, AC084759.1, AC084759.3, AC084759.2, UNC13C, AC010867.1, HNRNPA1P74, AC025272.1, AC011912.1, RSL24D1, RAB27A, AC018926.2, PIGBOS1, PIGB, CCPG1, AC018926.1, AC018926.3, DNAAF4-CCPG1, MIR628, C15orf65, DNAAF4, AC013355.1, PYGO1, AC012378.2, PRTG, AC012378.1, AC009997.1, NEDD4, CNOT6LP1, RN7SL568P, CD24P2, RFX7, AC084783.1, TEX9, AC068726.1, RNU6-1287P, HMGB1P33, AC084782.1, AC084782.2, MNS1, AC084782.3, AC090518.1, ZNF280D, Y_RNA, AC090517.4, AC090517.2, AC090517.3, AC090517.5, AC090517.1.
- chr15:71,096,952–71,783,383, 1 gene, copy number 10 (within-gene range 5–10): THSD4.
- chr15:71,147,650–72,900,260, 46 genes, copy number 10: THSD4-AS1, HMGB1P6, AC064799.2, AC064799.1, AC108861.1, NR2E3, AC104938.1, MYO9A, RNA5SP399, AC022872.1, EIF5A2P1, RNU2-65P, SENP8, AC020779.1, AC020779.2, GRAMD2A, PKM, PARP6, AC009690.3, AC009690.2, CELF6, AC009690.1, HEXA, HEXA-AS1, RPL12P35, TMEM202, TMEM202-AS1, PHBP20, AC079322.1, ARIH1, MIR630, AC100827.3, AC100827.5, AC100827.2, LINC02259, AC100827.4, AC100827.1, GOLGA6B, RN7SL853P, HIGD2B, AC009712.1, BBS4, ADPGK, ADPGK-AS1, AC103874.1, NPM1P42.
- chr15:89,748,661–96,842,384, 176 genes, copy number 7 (broad region; genes not listed).
- chr18:21,704,957–22,587,227, 26 genes, copy number 17: MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18.
- chr20:87,250–18,505,066, 357 genes, copy number 7 (broad region; genes not listed).
- chr20:19,756,390–64,313,132, 1,082 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
